Surgical pathology report (de-identified scan), TCGA case TCGA-BT-A2LA, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-BT-A2LA-01A (Primary Tumor).

FINAL DIAGNOSIS:

PART 1: LYMPH NODE, RIGHT PELVIC, EXCISION -
NINE (9) BENIGN LYMPH NODES.

PART 2: LYMPH NODE, LEFT PELVIC, EXCISION -
THREE (3) BENIGN LYMPH NODES.

PART 3: URETER, RIGHT DISTAL, BIOPSY -
BENIGN UROTHELIUM AND UNDERLYING SUBMUCOSA WITH REACTIVE CHANGES.

PART 4: URETER, LEFT DISTAL, BIOPSY -
BENIGN UROTHELIUM AND UNDERLYING SUBMUCOSA WITH REACTIVE CHANGES.

PART 5: PROSTATE, BLADDER, SEMINAL VESICLES, VAS DEFERENS, RADICAL CYSTECTOMY -
BLADDER:

- A. INVASIVE HIGH-GRADE UROTHELIAL CARCINOMA WITH PREDOMINANTLY SMALL CELL FEATURES (See comment).
- B. THE CARCINOMA MEASURES 4.5 CM IN GREATEST DIMENSION.
- C. THE CARCINOMA INVOLVES THE LEFT LATERAL WALL.
- D. THE CARCINOMA EXTENDS INTO AND THROUGH THE DETRUSOR MUSCLE (MUSCULARIS PROPRIA) TO INVOLVE THE PERIVESICAL SOFT TISSUE.
- E. FLAT CARCINOMA IN SITU (CIS) COMPONENT IS IDENTIFIED.
- F. THERE IS NO LYMPHOVASCULAR OR PERINEURAL INVASION.

PROSTATE:

- A. FOCAL HIGH-GRADE PROSTATIC INTRAEPITHELIAL NEOPLASIA (PIN).
- B. NON-NEOPLASTIC PROSTATE WITH BENIGN PROSTATIC HYPERPLASIA.

COMMENT:

The neoplasm consists of solid sheets of neoplastic cells, which at higher power have histological and cytological features of a small cell carcinoma. There is extensive necrosis. The cytoplasm have a high N:C ratio and there is prominent nuclear molding present. Immunostains for a neuroendocrine origin were performed. The neoplastic cells are positive for synaptophysin, NSE and CD56 and negative for chromogranin and pankheratin as well as thrombomodulin. The above immunoprofile confirms the neuroendocrine differentiation of the small cell component.

CASE SYNOPSIS:

SYNOPTIC DATA - PRIMARY URINARY BLADDER TUMORS

SPECIMEN TYPE: Radical cystoprostatectomy
TUMOR SITE: Left lateral wall
TUMOR SIZE: Greatest dimension: 4.7 cm
HISTOLOGIC TYPE: Small cell carcinoma
ASSOCIATED EPITHELIAL LESIONS: None identified
HISTOLOGIC GRADE: Urothelial carcinoma - High-grade
TUMOR CONFIGURATION: Solid/nodule
PATHOLOGIC STAGING (pTNM): pT3a
pN0
Number of nodes examined: 12
Number of nodes involved: 0

MARGINS: pMX
Margins uninvolved by invasive carcinoma
VENOUS/LYMPHATIC (LARGE/SMALL) VESSEL INVASION (V/L): Absent
DIRECT EXTENSION OF INVASIVE TUMOR: None identified
ADDITIONAL PATHOLOGIC FINDINGS: Urothelial carcinoma in situ

Collection Data:

1CD-0-3

carcinoma, urothelial, NOS

8/20/3

Site: bladder, wall, lateral

C67-2

hw
8/19/11

Source: NCI Genomic Data Commons file 9a762b89-3213-40ec-8405-70a65e6083d9 (TCGA-BT-A2LA.872A05BE-966A-4757-9FED-9FD4FFA460CC.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).